Surgical pathology report (de-identified scan), TCGA case TCGA-B9-4117, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-4117-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Surgical Pathology Report

Accession #:

Diagnosis:

A: Fat, hilar, NOS, removal

- No tumor seen.

B: Kidney, left, hand assisted laparoscopic nephrectomy

Histologic tumor type/subtype: papillary renal cell carcinoma, type 2

Histologic grade: Fuhrman nuclear grade 3

Tumor size (greatest dimension): 8.4 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: negative

Gerota's fascia: negative

Renal vein: negative

Ureter: negative

Venous (large vessel): negative

Lymphatic (small vessel): negative

Adjacent organs: not applicable

Histologic assessment of surgical margins:

Perirenal adipose tissue: negative

Gerota's fascia: negative

Renal vein: negative

Renal artery: negative

Ureter: negative

Adrenal gland: not submitted

[page 2 of 4]
Lymph nodes: none identified

AJCC Staging: pT2 pNx pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

with clinical diagnosis of left renal mass.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "hilar fat." It holds a 4.8 x 2.0 x 1.6 cm somewhat disrupted fragment of red/yellow lobulated fibroadipose tissue. The fragment is palpated and no lymph node candidates are readily identified. The fat is serially sectioned and entirely submitted in blocks A1-A4, [REDACTED].

Container B:

Specimen fixation: formalin

Type of specimen: hand assisted laparoscopic nephrectomy

Side of specimen: left

Size and weight of specimen: 550 grams, 18 x 11 x 7.5 cm nephrectomy specimen (kidney and fat); the kidney is approximately 13.8 x 7.5 x 7.5 cm

Orientation: The specimen is received previously incised by the surgeon. The perinephric fat is markedly disrupted. The entire length of the kidney is received opened exposing the tumor. Margin evaluation will be difficult given the disrupted nature of this specimen.

The kidney capsule in the area of the previous incision is inked blue.

Presence/absence of adrenal gland: Absent; the superior perinephric fat is disrupted along with the vast majority of the remaining perinephric fat

[page 3 of 4]
Tumor description/site: Tumor is a mid kidney anterior cortical lesion with a solid, somewhat soft yellow diffusely brown and hemorrhagic cut surface. A portion of the tumor is missing as is adjacent normal kidney. These are presumed to be taken [REDACTED]

Tumor size: 8.4 x 7.3 x 6.0 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: The tumor is abutting the overlying blue inked capsule. Given the perinephric fat is not disrupted, it is believed to be not attached. Exact determination of confinement cannot be determined.

Extent of invasion:

Perirenal adipose tissue: cannot determine

Gerota' s fascia: absent

Renal vein: tumor does not involve

Ureter: tumor does not involve

Other organs: n/a

Surgical margins:

Perirenal adipose tissue: cannot determine

Renal vein: negative

Renal artery: negative

Ureter: negative

Description of kidney away from tumor: The remainder of the kidney consists of dark red/brown renal parenchyma with a distinct corticomedullary junction. The cortex is approximately 1 cm and the medulla is up to 1.8 cm. There is no evidence of papillary necrosis. The renal pelvis is unremarkable.

Lymph nodes (hilar): There is scant hilar adipose tissue present. No hilar lymph node candidates are identified. Hilar fat was submitted as specimen A.

Other significant findings: none

Tissue submitted for special investigations: Tumor was taken by Tissue Procurement.

Digital photograph taken: no

[page 4 of 4]
Block summary:

- B1 - ureteral and hilar vascular margins, en face
- B2 - tumor overlying blue inked capsule and adjacent normal kidney
- B3 - tumor
- B4 - tumor and adjacent renal sinus
- B5 - additional tumor and adjacent kidney
- B6 - normal kidney
- B7-B8 - disrupted perirenal fat from the approximate area of the tumor

Source: NCI Genomic Data Commons file 272f1738-cc3d-4ddd-8e71-a74f7ddcd25f (TCGA-B9-4117.DFEE0715-13F6-4D97-806B-0DD5ACCF4647.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).